Somatic mutation profile of tumor specimen MMRF_1432_2_BM_CD138pos (aliquot MMRF_1432_2_BM_CD138pos_T1_KBS5U_L05834) from MMRF case MMRF_1432, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 67.8 years (24,764 days).
Specimen MMRF_1432_2_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3cce8541-9d7a-4691-bcfc-15a0422a7496.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1432_1_PB_CD3pos (Blood Derived Normal), aliquot MMRF_1432_1_PB_CD3pos_C2_KAS5U_L01715; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a014dfe3-f35c-40be-b91d-90de195f0512

The open-access MAF lists 54 somatic variants for this specimen: 21 protein-altering or splice-affecting, 3 silent, 30 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, 3'UTR 16, 5'UTR 4, Intron 3, 5'Flank 3, Silent 3, RNA 2, Splice Site 2, 3'Flank 2, Nonsense Mutation 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- A1CF | c.1199G>A p.G400D (on ENST00000373993 / NM_138932.2; = p.G392D on NM_014576.4) | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); catalogued as rs769418567; called by mutect2, varscan2
- ANO4 | c.2492G>A p.R831Q (on ENST00000392977 / NM_001286615.2; = p.R796Q on NM_178826.4) | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (0.63); PolyPhen benign (0.052); catalogued as rs868314489, COSV54590940; called by muse, mutect2, varscan2
- DCUN1D1 | c.498G>C p.K166N | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); catalogued as COSV53045486; called by muse, mutect2
- HHAT | c.749G>A p.R250H | Missense Mutation (SNP) | VAF 4/74 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs148639278; called by muse, mutect2
- IFNL1 | c.143C>T p.A48V | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.023); catalogued as rs1285881612; called by muse, mutect2
- IGKV4-1 | c.283A>G p.T95A | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.168); catalogued as rs578059335; called by muse, varscan2
- ITGA3 | c.394G>A p.G132S | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.255); catalogued as rs780044729; called by muse, mutect2, varscan2
- OSBPL5 | c.2050C>T p.R684W | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs746630605, COSV55140887; called by mutect2, varscan2
- PLK1 | c.1264G>A p.G422S | Missense Mutation (SNP) | VAF 5/63 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55621597, COSV55622446; called by muse, mutect2
- STON1 | c.1951C>A p.L651M | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); catalogued as COSV59134877; called by muse, mutect2, varscan2
- CNST | c.518T>C p.L173P | Missense Mutation (SNP) | VAF 7/80 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- COL1A2 | c.385G>T p.A129S | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT tolerated (0.7); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- DNAH5 | c.12667T>G p.F4223V | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); called by muse, mutect2
- KHDC1L | c.296-2A>G p.X99_splice | Splice Site (SNP) | VAF 15/55 reads (27%) | called by muse, mutect2, varscan2
- MAPK7 | c.526G>A p.A176T | Missense Mutation (SNP) | VAF 4/49 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- MRPL38 | c.547G>A p.D183N | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.54); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PRG4 | c.3253T>G p.S1085A | Missense Mutation (SNP) | VAF 9/92 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.14); called by muse, mutect2
- PSMG1 | c.393+1G>A p.X131_splice | Splice Site (SNP) | VAF 9/41 reads (22%) | called by mutect2, varscan2
- REXO1 | c.3091-7C>T | Splice Region (SNP) | VAF 10/46 reads (22%) | called by muse, mutect2, varscan2
- SLC25A18 | c.95C>T p.A32V | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT tolerated (0.73); PolyPhen benign (0.098); called by muse, mutect2
- YLPM1 | c.6094G>T p.E2032* | Nonsense Mutation (SNP) | VAF 6/70 reads (9%) | called by muse, mutect2
- ANKK1 | c.1746C>T p.Y582= | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as rs373856752; called by mutect2, varscan2
- CAMK2B | c.567G>A p.E189= | Silent (SNP) | VAF 5/26 reads (19%) | catalogued as rs1204336480; called by mutect2, varscan2
- RGS12 | c.3879G>A p.K1293= | Silent (SNP) | VAF 12/39 reads (31%) | catalogued as COSV58750534; called by muse, mutect2, varscan2
- AC092818.1 | n.454T>A | RNA (SNP) | VAF 7/44 reads (16%) | called by mutect2, varscan2
- AC112695.1 | n.520T>A | RNA (SNP) | VAF 6/40 reads (15%) | called by muse, mutect2, varscan2
- ANKEF1 | c.*417G>A | 3'UTR (SNP) | VAF 4/16 reads (25%) | catalogued as rs554557726; called by mutect2, varscan2
- CEMIP | c.*1548C>T | 3'UTR (SNP) | VAF 9/85 reads (11%) | called by muse, mutect2, varscan2
- CHORDC1 | c.563+69A>T | Intron (SNP) | VAF 3/43 reads (7%) | called by muse, mutect2
- CLDN15 | c.-143G>C | 5'UTR (SNP) | VAF 6/44 reads (14%) | called by muse, mutect2, varscan2
- EDNRA | c.*482A>G | 3'UTR (SNP) | VAF 6/48 reads (13%) | called by muse, mutect2, varscan2
- EIF3J | chr15:44536832 G>A | 5'Flank (SNP) | VAF 7/68 reads (10%) | catalogued as rs1421276742; called by muse, mutect2, varscan2
- ELK3 | c.*1049dup | 3'UTR (INS) | VAF 9/48 reads (19%) | called by mutect2, pindel, varscan2
- ELOVL1 | c.*223C>T | 3'UTR (SNP) | VAF 6/42 reads (14%) | called by muse, mutect2, varscan2
- GRID2 | c.-380G>T | 5'UTR (SNP) | VAF 6/14 reads (43%) | called by muse, mutect2, varscan2
- HLCS | chr21:36749611 G>A | 3'Flank (SNP) | VAF 5/47 reads (11%) | called by mutect2, varscan2
- IL1RAP | c.*1207A>T | 3'UTR (SNP) | VAF 12/35 reads (34%) | called by muse, mutect2, varscan2
- KCTD16 | c.*2458C>T | 3'UTR (SNP) | VAF 3/42 reads (7%) | called by muse, mutect2
- KIAA1755 | c.*626C>T | 3'UTR (SNP) | VAF 5/18 reads (28%) | called by muse, mutect2
- LRP4 | c.*1217C>T | 3'UTR (SNP) | VAF 15/41 reads (37%) | called by muse, mutect2, varscan2
- NHLH2 | c.-8-413C>T | Intron (SNP) | VAF 7/48 reads (15%) | called by muse, mutect2
- NR0B1 | c.*299T>G | 3'UTR (SNP) | VAF 3/20 reads (15%) | catalogued as rs1215810806; called by muse, mutect2
- NT5DC3 | c.*627T>C | 3'UTR (SNP) | VAF 3/46 reads (7%) | called by muse, mutect2
- PRR4 | c.-6T>C | 5'UTR (SNP) | VAF 6/78 reads (8%) | called by muse, mutect2
- RN7SL319P | chr15:75783004 G>T | 5'Flank (SNP) | VAF 8/43 reads (19%) | called by muse, mutect2, varscan2
- SLC6A2 | chr16:55705276 G>A | 3'Flank (SNP) | VAF 22/52 reads (42%) | called by muse, mutect2, varscan2
- SNRNP40 | c.*266A>T | 3'UTR (SNP) | VAF 8/77 reads (10%) | called by muse, varscan2
- SPTA1 | c.*60A>T | 3'UTR (SNP) | VAF 18/218 reads (8%) | called by muse, mutect2
- TMEM165 | c.-197C>G | 5'UTR (SNP) | VAF 6/20 reads (30%) | catalogued as rs532235169; called by muse, mutect2, varscan2
- TRAM1L1 | c.*362T>G | 3'UTR (SNP) | VAF 11/42 reads (26%) | called by muse, varscan2
- UCK2 | chr1:165827566 G>A | 5'Flank (SNP) | VAF 4/34 reads (12%) | called by muse, varscan2
- UROS | c.661-467A>C | Intron (SNP) | VAF 3/40 reads (8%) | called by muse, mutect2
- VPS13D | c.*1359G>C | 3'UTR (SNP) | VAF 3/50 reads (6%) | called by muse, mutect2
- ZMAT1 | c.*175_*196delinsGCCCAAACTTAACCTCTGAG | 3'UTR (DEL) | VAF 5/33 reads (15%) | called by pindel, varscan2*
